FM case AD1457 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mesothelial Neoplasms; Primary site: Heart, mediastinum, and pleura.
https://portal.gdc.cancer.gov/cases/aab0cc56-ed79-4b93-a9c4-610efe6d824e

Male, 66.4 years: Mesothelioma, NOS (ICD-O-3 9050/3) of the pleura. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
